Somatic mutation profile of tumor specimen TCGA-N5-A4RM-01A (aliquot TCGA-N5-A4RM-01A-11D-A28R-08) from TCGA case TCGA-N5-A4RM, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVB; Age at diagnosis: 62.7 years (22,886 days).
Specimen TCGA-N5-A4RM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec7e064a-1fd7-4a98-9d3b-3e7b54783512.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N5-A4RM-10A (Blood Derived Normal), aliquot TCGA-N5-A4RM-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eeaab9e1-a707-4c47-bd73-a7103af3025a

The open-access MAF lists 46 somatic variants for this specimen: 35 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 9, Frame Shift Del 3, Nonsense Mutation 2, RNA 2, Frame Shift Ins 1, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMC1A | c.2131C>T p.R711W | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587784409, CM071102, COSV59127821; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.731G>A p.G244D | Missense Mutation (SNP) | VAF 58/60 reads (97%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs985033810, CM056069, CM070298, COSV52661058, COSV52724858, COSV52839584; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARAP3 | c.2701G>A p.A901T | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs1406919159; called by muse, mutect2, varscan2
- ATP8B2 | c.2893C>T p.R965W (on ENST00000672630; = p.R932W on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 106/218 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs768053191, COSV59247540; called by muse, mutect2, varscan2
- FASTKD5 | c.1061G>T p.R354L | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs772486694, COSV99418845; called by muse, mutect2
- FDX1 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs368983211, COSV52799844; called by muse, mutect2, varscan2
- GLYCTK | c.37C>T p.R13* | Nonsense Mutation (SNP) | VAF 28/33 reads (85%) | catalogued as rs910401729, COSV59793447; called by muse, mutect2, varscan2
- GRIN2A | c.1448G>T p.G483V | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58061852; called by muse, mutect2, varscan2
- HASPIN | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 37/41 reads (90%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as rs756698026; called by muse, mutect2, varscan2
- INTS11 | c.1183G>A p.A395T | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs778570936; called by muse, mutect2, varscan2
- KMT2C | c.13462G>A p.A4488T | Missense Mutation (SNP) | VAF 81/174 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753793539, COSV51422873, COSV51455379; called by muse, mutect2, varscan2
- KRTAP19-6 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 140/316 reads (44%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.003); catalogued as rs146590456; called by muse, mutect2, varscan2
- LPA | c.4390C>T p.R1464* | Nonsense Mutation (SNP) | VAF 83/169 reads (49%) | catalogued as rs1297292947; called by muse, mutect2, varscan2
- LRIT1 | c.99C>G p.I33M | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV100812966; called by muse, mutect2
- LRP1 | c.8458G>A p.D2820N | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.095); catalogued as rs755765930, COSV54507256; called by muse, mutect2, varscan2
- OR6C2 | c.762C>G p.I254M | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.913); catalogued as COSV100498715, COSV59515823; called by muse, mutect2, varscan2
- PTPRT | c.3602G>A p.R1201Q | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs372862828, COSV100631324, COSV61969750; called by muse, mutect2, varscan2
- ZNF230 | c.1055del p.L352* | Frame Shift Del (DEL) | VAF 73/279 reads (26%) | catalogued as COSV71273777; called by mutect2, pindel, varscan2
- CSPP1 | c.3055T>G p.F1019V (on ENST00000676605; = p.F978V on NM_024790.6) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DMTN | c.815A>C p.D272A | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IFI16 | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- KRT72 | c.803T>G p.I268S | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- L3MBTL1 | c.1940C>T p.P647L (on ENST00000418998 / NM_001377303.1; = p.P557L on NM_015478.7) | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); called by muse, mutect2
- MAST1 | c.1486_1488del p.R496del | In Frame Del (DEL) | VAF 58/69 reads (84%) | called by mutect2, pindel, varscan2
- MYH2 | c.2891A>C p.E964A | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- OR5L2 | c.548del p.P183Lfs*3 | Frame Shift Del (DEL) | VAF 110/278 reads (40%) | called by mutect2, varscan2
- PDGFRB | c.2479C>G p.L827V | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- PI4KA | c.4315G>T p.D1439Y | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- RNF216 | c.1665G>T p.L555F (on ENST00000425013 / NM_207116.3; = p.L612F on NM_207111.4) | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- SCN2A | c.611T>A p.V204E | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- SHB | c.930_931insCTCG p.D311Lfs*20 | Frame Shift Ins (INS) | VAF 63/130 reads (48%) | called by muse*, mutect2, pindel*
- SPEN | c.674_687del p.T225Rfs*22 | Frame Shift Del (DEL) | VAF 46/148 reads (31%) | called by mutect2, pindel, varscan2
- TBC1D17 | c.323C>G p.A108G | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.127); called by muse, mutect2
- TRA2B | c.182G>C p.R61T | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- ZFP36L2 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ADRA1A | c.1179C>T p.G393= | Silent (SNP) | VAF 104/207 reads (50%) | catalogued as rs143947423, COSV52357348; called by muse, mutect2, varscan2
- BCAS1 | c.819C>T p.D273= | Silent (SNP) | VAF 43/125 reads (34%) | catalogued as rs146823292; called by muse, mutect2, varscan2
- EIPR1 | c.177C>A p.V59= | Silent (SNP) | VAF 39/41 reads (95%) | called by muse, mutect2, varscan2
- ITGAE | c.2634G>A p.L878= | Silent (SNP) | VAF 119/136 reads (88%) | catalogued as rs796218865; called by muse, mutect2, varscan2
- LCT | c.1245G>A p.R415= | Silent (SNP) | VAF 62/157 reads (39%) | catalogued as rs768656506; called by muse, mutect2, varscan2
- LYZL4 | c.189C>T p.Y63= | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as rs571590107, COSV99821097; called by muse, mutect2, varscan2
- NOC4L | c.846G>A p.P282= | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as rs144597773; called by muse, mutect2, varscan2
- PCDHGA10 | c.570C>T p.A190= | Silent (SNP) | VAF 20/58 reads (34%) | called by muse, mutect2, varscan2
- RNF216 | c.1857G>A p.K619= (on ENST00000425013 / NM_207116.3; = p.K676= on NM_207111.4) | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV66290439, COSV66291323; called by muse, mutect2
- LINC00482 | n.1170T>C | RNA (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- SNORD116-4 | n.19C>G | RNA (SNP) | VAF 101/132 reads (77%) | catalogued as rs576130317; called by muse, mutect2, varscan2
